Surgical pathology report (de-identified scan), TCGA case TCGA-CD-8525, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site ILSBio, specimen TCGA-CD-8525-01A (Primary Tumor).

[page 1 of 5]
Clinical Information

HISTORY OF PRESENT ILLNESS

Chief Complaints: Abdominal pain; constipation.

Symptoms: weight loss; tired of eating

Clinical Findings:

Performance Scale (Karnofsky Score):

- ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day
☒ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS

Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)			
				/	/	To	/ /
				/	/	To	/ /
				/	/	To	/ /
				/	/	To	/ /
				/	/	To	/ /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY	
Menopausal Status ☐ Pre-menopausal ☐ Peri-Menopausal ☒ Post-menopausal	Date of First Menses Don't remember Date of Last Menses Don't remember
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: Don't know	☐ Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status ☐ YES ☒ NO	TYPE	Packs/day	Duration (yrs)	When Quit (yr)
Alcohol Consumption				
Current Status ☐ YES ☒ NO	TYPE	Drinks/day	Duration (yrs)	When Quit (yr)
Drug Use				
Current Status ☐ YES ☒ NO	TYPE	Frequency	Duration (yrs)	When Quit (yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV			CEA	☐ Negative ☐ Positive: _____		
Hep B	☒ Negative ☐ Positive: _____	//	CA 15-3	☐ Negative ☐ Positive: _____		
Hep C	☒ Negative ☐ Positive: _____	//	CA 19-9	☐ Negative ☐ Positive: _____		
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____		
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____		
B/T Cell Markers:						

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy	A tumour was found at the pylorus.	
MRI		
Biopsy		

CLINICAL DIAGNOSIS	
Preoperative Clinical Diagnosis	
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis
Clinical Staging	Date of Diagnosis
T 3 N 1 M 0 Stage: III	

Treatment Information

SURGICAL TREATMENT			
Procedure			Date of Procedure
Extended Gastrectomy			
Primary Tumor			
Organ	Detailed Location	Size	
Stomach tumor	pylorus	3 x 2.5 x 2 cm	
Extension of Tumor			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes			
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location	Size	
Surgical Staging			
T 3 N 1 M 0 Stage: IV			

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
11 min		12 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Stomach tumor	3 x 2.5 x 2 cm	pylorus	6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 3		N 1	M 0
Stage: III			

Notes:

Stomach nodes 2 (positive)
2 vials of stomach nodes in nitrogen.

[page 5 of 5]
1. Histological pattern:

CELL DISTRIBUTION			STRUCTURAL PATTERN		
	+	-		+	-
Diffuse			Streaming		
Mosaic		X	Storiform		
Necrosis	X		Fibrosis		
Lymphocytic Infiltration	X		Palisading		
Vascular Invasion		X	Cystic Degeneration		
Clusterized	X		Bleeding		
Alveolar Formation		X	Myxoid Change		
Indian File		X	Psammoma/Calcification		

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamous Cell			Glandular cell	X		Round Cell			Large Cell		
Spindle Cell			Cell Stratification	X		Fibroblast			Small Cell		
Keratin			Secretion	X		Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole	X		Lipoblast			Inflam. Cell		
Pearl			Gland formation	X		Myoblast			Plasma Cell		

Otherwise Specified:

D1 60% D2: 70% D3 70% D4 60%

Neovasc 1/2

2. Cellular Differentiation:

Well	Moderately	Poor
		X

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis			X	X
Hyperchromatism			X	X
Nucleolar Prominent			X	X
Multinucleated Giant Cell			X	X
Mitotic Activity			X	X
Nuclear Grade				

Histological Diagnosis: Microscopic Adenocarcinoma G3

Comments: M, M2: Carcinoma metastasized to LN

Source: NCI Genomic Data Commons file 56c81c85-f82e-4ead-9879-c61af50d0c7d (TCGA-CD-8525.A5C6498B-847D-4665-AE8E-13EBCB082B4F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).